Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6801, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6801-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy
Tumor site: Stomach
Tumor size: 9 x 7 x 1 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Tumor extent: Adjacent structures (specify) - greater omentum
Lymph nodes: 0/8 positive for metastasis (Regional 0/8)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file e53891f7-16b5-445c-b22b-750f55ec93a8 (TCGA-BR-6801.975674C1-7CB6-4E9E-B9E4-32FF2504E260.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).